MMRF case MMRF_1971 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fea6a14e-c84a-473e-b106-f00997f5bb22

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.0 years (24,123 days); ISS stage: I; Days to last known disease status: 972 days (2.7 years); Days to last follow up: 972 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 364 days.
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 357 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 1): M Protein 1.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 49.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.476 mg/dL; Immunoglobulin G 19.6 g/L; Immunoglobulin A 0.0935 g/L; Immunoglobulin M 0.233 g/L; Beta 2 Microglobulin 2.73 µg/mL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 2.17 ×10⁹/L; Absolute Neutrophil 0.58 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 72.5 µmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 5.72 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 63 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.471 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.087 mg/dL; Immunoglobulin G 4.01 g/L; Immunoglobulin A 0.0625 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 4.8 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.15 ×10⁹/L; Absolute Neutrophil 3.25 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 65.4 µmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 5.61 mmol/L.
- Day 168 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.786 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.059 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.106 g/L; Immunoglobulin M 0.555 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.96 ×10⁹/L; Absolute Neutrophil 4.45 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.33 mmol/L; Albumin 43.3 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 252 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.047 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.621 mg/dL; Immunoglobulin G 4.09 g/L; Immunoglobulin A 0.121 g/L; Immunoglobulin M 0.655 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 8.32 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 65.4 µmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 6.38 mmol/L.
- Day 336 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.869 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.047 mg/dL; Immunoglobulin G 4.7 g/L; Immunoglobulin A 0.122 g/L; Immunoglobulin M 0.734 g/L; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.13 ×10⁹/L; Absolute Neutrophil 3.99 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 71.6 µmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 420 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.123 mg/dL; Immunoglobulin G 5.17 g/L; Immunoglobulin A 0.147 g/L; Immunoglobulin M 0.727 g/L; Beta 2 Microglobulin 2.29 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.09 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 63.6 µmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 504 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.172 mg/dL; Immunoglobulin G 6.79 g/L; Immunoglobulin A 0.258 g/L; Immunoglobulin M 1.11 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.54 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 63.6 µmol/L; Calcium 2.3 mmol/L; Albumin 48 g/L; Total Protein 6.7 g/dL; Glucose 6.22 mmol/L.
- Day 595 (ECOG 1): M Protein 0.48 g/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 0.279 g/L; Immunoglobulin M 1.63 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.74 ×10⁹/L; Absolute Neutrophil 3.84 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 71.6 µmol/L; Calcium 2.26 mmol/L; Albumin 43.9 g/L; Total Protein 6.42 g/dL; Glucose 4.46 mmol/L.
- Day 722 (ECOG 1): M Protein 1.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.696 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 1.51 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 87.5 µmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.83 mmol/L.
- Day 816 (ECOG 1): M Protein 1.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.646 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 1.27 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.55 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 69.8 µmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.78 mmol/L.
- Day 886 (ECOG 1): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.96 g/L; Beta 2 Microglobulin 3.26 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.95 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 76.9 µmol/L; Calcium 2.28 mmol/L; Albumin 36.2 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 972 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.964 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.25 ×10⁹/L; Absolute Neutrophil 3.02 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.08 mmol/L; Albumin 37.5 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -23: Weight: 59 kg; Height: 150 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1971_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_1971_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
